Gene-level copy-number profile of tumor specimen TCGA-ZR-A9CJ-01B from TCGA case TCGA-ZR-A9CJ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.0 years (23,752 days).
Specimen TCGA-ZR-A9CJ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.f7df53d1-08c6-4e23-862a-8170013e56ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZR-A9CJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6d25222a-1816-44de-a448-10ae2b3bb439

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,240; copy number 2: 13,742; copy number 3: 19,569; copy number 4: 15,016; copy number 5: 6,978; copy number 6: 1,200; copy number 7: 757; copy number 8: 344; copy number 9: 592; copy number 10: 25; copy number 11: 6; copy number 12: 91; copy number 14: 99; copy number 16: 17; copy number 20: 108; copy number 32: 3; copy number 92: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZR-A9CJ-01B-11D-A386-01): tumor purity 0.33, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,039,761–59,063,503, 1 gene (within-gene range 0–2): AC092343.1.
- chr20:15,280,764–15,280,873, 1 gene: RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,067 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:173,351,689–174,160,165, 26 genes, copy number 8: AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT.
- chr1:174,367,105–174,368,039, 1 gene, copy number 8: AL022400.1.
- chr1:241,132,272–241,305,882, 2 genes, copy number 8: MIR3123, AL592076.1.
- chr2:49,233,794–49,233,899, 1 gene, copy number 7: RNU6-439P.
- chr3:60,730,055–65,193,509, 48 genes, copy number 8–14: AC104164.1, PPIAP71, U3, PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040.
- chr3:65,359,268–65,359,717, 1 gene, copy number 11: AC121493.1.
- chr6:25,061,626–25,452,263, 1 gene, copy number 7 (within-gene range 4–7): CMAHP.
- chr6:25,140,003–36,639,672, 684 genes, copy number 7 (broad region; genes not listed).
- chr6:46,997,708–47,309,905, 2 genes, copy number 7: ADGRF1, TNFRSF21.
- chr6:145,296,545–147,390,476, 27 genes, copy number 8: AL023283.1, EPM2A, RNU1-33P, AL031119.1, AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT, SHPRH, GRM1, FUNDC2P3, RNA5SP222, AL035698.1, RAB32, AL359547.1, ADGB, AL359547.2, RNU6-906P, KATNBL1P6, STXBP5-AS1, AL138916.1, AL138916.2, LUADT1, STXBP5.
- chr7:7,156,934–26,995,239, 252 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:6,708,642–13,705,506, 285 genes, copy number 8–20 (broad region; genes not listed).
- chr8:82,033,533–82,961,926, 1 gene, copy number 8 (within-gene range 5–8): AC060765.2.
- chr8:82,514,568–83,100,846, 4 genes, copy number 8: AC060765.1, AC105031.2, AC105031.1, AC090095.1.
- chr8:104,981,164–105,011,568, 3 genes, copy number 10: AC090142.2, AC090142.3, AC090142.1.
- chr10:61,901,684–62,096,944, 1 gene, copy number 10 (within-gene range 5–10): ARID5B.
- chr10:122,271,296–126,398,789, 84 genes, copy number 8 (broad region; genes not listed).
- chr11:75,100,563–75,206,549, 1 gene, copy number 20 (within-gene range 5–20): SLCO2B1.
- chr11:75,206,048–94,114,208, 371 genes, copy number 8–20 (broad region; genes not listed).
- chr11:107,908,420–109,583,907, 26 genes, copy number 9 (within-gene range 3–9): AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1.
- chr12:24,993,424–29,784,759, 99 genes, copy number 7–92 (within-gene range 4–92) (broad region; genes not listed).
- chr15:84,748,592–84,806,445, 1 gene, copy number 16 (within-gene range 2–16): ZNF592.
- chr15:84,817,356–87,029,052, 42 genes, copy number 9–16 (within-gene range 2–16): ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP, AC104229.1, LINC01584, AGBL1, RNA5SP400, AC016180.2, AC016180.1, AGBL1-AS1, AC012229.1.
- chr15:89,575,469–91,743,955, 91 genes, copy number 12 (broad region; genes not listed).
- chr16:89,560,677–89,740,925, 13 genes, copy number 8 (within-gene range 5–8): RPL13, SNORD68, CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276.

Autosomal genes at a single copy (total copy number 1): 569. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
